Somatic mutation profile of tumor specimen TCGA-D8-A27T-01A (aliquot TCGA-D8-A27T-01A-11D-A16D-09) from TCGA case TCGA-D8-A27T, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 53.6 years (19,591 days).
Specimen TCGA-D8-A27T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ad07a28-249e-402f-93ef-d80663242af7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A27T-10A (Blood Derived Normal), aliquot TCGA-D8-A27T-10A-01D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7a7f1ee-73dc-4ae2-88b3-4b7e2cc43160

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 15, Silent 7, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.1137G>A p.T379= | Splice Region (SNP) | VAF 16/30 reads (53%) | catalogued as rs587783050, CS060517, COSV55733400; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALDH5A1 | c.1439G>A p.R480K | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1055012664, COSV100708929; ClinVar: uncertain significance; called by muse, mutect2
- EHMT1 | c.3136G>A p.V1046M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); catalogued as COSV71777877; called by muse, mutect2, varscan2
- EIF2AK4 | c.3330G>T p.M1110I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.335); catalogued as COSV55468756; called by muse, mutect2, varscan2
- GAL3ST4 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs199565529, COSV57586510; called by muse, mutect2, varscan2
- GNPNAT1 | c.407+1G>T p.X136_splice | Splice Site (SNP) | VAF 33/124 reads (27%) | catalogued as rs764695387, COSV53591519; called by muse, mutect2, varscan2
- GPR137B | c.564G>T p.K188N | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.311); catalogued as COSV63990985; called by muse, mutect2, varscan2
- GUSB | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV59222026; called by muse, mutect2, varscan2
- MELTF | c.178G>C p.A60P | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as COSV56381663; called by muse, mutect2, varscan2
- PCDH9 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs868294906, COSV60525236; called by muse, mutect2
- PGK1 | c.725T>C p.F242S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV64832082; called by muse, mutect2, varscan2
- PLXNB2 | c.1984A>G p.M662V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.221); catalogued as rs748937712; called by muse, varscan2
- RIN1 | c.803C>G p.P268R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100254751, COSV60926821; called by muse, mutect2, varscan2
- SCN2A | c.3530G>A p.R1177Q | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs773202451, COSV51842580, COSV99332198; called by muse, mutect2, varscan2
- TMPRSS15 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53040485; called by muse, mutect2, varscan2
- PIGW | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ARMCX5 | c.1203C>T p.I401= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1182334638, COSV55766695; called by muse, mutect2, varscan2
- CDH7 | c.372G>A p.A124= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs375091808; called by muse, mutect2, varscan2
- GNL3 | c.1084C>T p.L362= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs1256087777, COSV99804124; called by muse, mutect2
- PADI3 | c.963T>C p.D321= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs756806020, COSV64934603; called by muse, varscan2
- PCDHA4 | c.1671C>T p.D557= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1451689285, COSV63545662; called by muse, mutect2, varscan2
- PITPNM1 | c.3363C>T p.A1121= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs777152377, COSV54160806; called by muse, mutect2, varscan2
- SCT | c.333C>T p.G111= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs148783373; called by muse, mutect2, varscan2
